Somatic mutation profile of tumor specimen 0DFBLR from CCDI case PBBRWZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.9 years (1,784 days).
Specimen 0DFBLR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7997ec3-53a0-4694-aaf7-07e7c0add774.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF6VC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a954253f-a2b9-41bc-9a3e-5306ca12c481

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT9 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 198/483 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100321485; called by muse, mutect2, varscan2
- ALG1 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 330/837 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs377600706; called by muse, mutect2, varscan2
- ANO10 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 214/489 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767044966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 20/535 reads (4%) | catalogued as COSV59989381; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 37/1494 reads (2%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ZNF624 | c.2068_2075dup p.E693Ifs*106 | Frame Shift Ins (INS) | VAF 170/483 reads (35%) | called by mutect2, varscan2
- TM4SF18 | c.210G>A p.L70= | Silent (SNP) | VAF 272/680 reads (40%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-8509G>A | Intron (SNP) | VAF 452/1040 reads (43%) | catalogued as rs1330871533, COSV52539876; called by muse, mutect2, varscan2
- CFLAR | c.606+1026T>A | Intron (SNP) | VAF 26/555 reads (5%) | called by muse, mutect2
